Somatic mutation profile of tumor specimen TCGA-B0-5705-01A (aliquot TCGA-B0-5705-01A-11D-1534-10) from TCGA case TCGA-B0-5705, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 65.0 years (23,746 days).
Specimen TCGA-B0-5705-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 255ab593-0ce7-43f7-8dcb-570992dc0ae7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5705-11A (Solid Tissue Normal), aliquot TCGA-B0-5705-11A-01D-1534-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a48d7c41-6f6e-40aa-884b-76b891f72071

The open-access MAF lists 78 somatic variants for this specimen: 59 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 18, Frame Shift Del 7, Nonsense Mutation 5, Frame Shift Ins 2, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRB1 | c.4168C>T p.R1390* | Nonsense Mutation (SNP) | VAF 32/104 reads (31%) | catalogued as rs763324776, CM130803, COSV66337060; ClinVar: pathogenic; called by muse, mutect2, varscan2
- VHL | c.563T>C p.L188P | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1559429824, CD962181, CM114581, CM951299, CM982013, COSV56546651, COSV56549626, COSV56559142, COSV56568527; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS18 | c.3281G>A p.R1094Q | Missense Mutation (SNP) | VAF 58/245 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as rs373807615, COSV51407429; called by muse, mutect2, varscan2
- ALKAL2 | c.401G>T p.C134F | Missense Mutation (SNP) | VAF 76/258 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55243781; called by muse, mutect2, varscan2
- ANKRD7 | c.571C>T p.Q191* | Nonsense Mutation (SNP) | VAF 66/248 reads (27%) | catalogued as COSV54555235, COSV99501189; called by muse, mutect2, varscan2
- ARID1A | c.1199del p.P400Hfs*33 | Frame Shift Del (DEL) | VAF 12/51 reads (24%) | catalogued as COSV61389858; called by mutect2, pindel, varscan2
- BCORL1 | c.358G>T p.D120Y | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV54398680; called by muse, mutect2, varscan2
- BMP3 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV51087163; called by muse, mutect2, varscan2
- CALCOCO1 | c.1700C>G p.P567R | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV50415293; called by muse, mutect2
- CERCAM | c.1184A>T p.H395L | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65711193; called by muse, mutect2, varscan2
- CHKB | c.679A>G p.K227E | Missense Mutation (SNP) | VAF 105/378 reads (28%) | SIFT tolerated (0.67); PolyPhen benign (0.155); catalogued as COSV56417261; called by muse, mutect2, varscan2
- CKAP4 | c.907A>G p.R303G | Missense Mutation (SNP) | VAF 78/208 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV65172734; called by muse, mutect2
- CYFIP2 | c.2108T>C p.L703P (on ENST00000616178 / NM_001291722.2; = p.L678P on NM_014376.4) | Missense Mutation (SNP) | VAF 74/359 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59041818, COSV59051872; called by muse, mutect2, varscan2
- DPY19L4 | c.941C>A p.A314D | Missense Mutation (SNP) | VAF 142/617 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs977914403, COSV68963154; called by muse, mutect2, varscan2
- EXOSC5 | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55370755, COSV55371334; called by muse, mutect2, varscan2
- FTL | c.76C>A p.Q26K | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.182); catalogued as COSV53170632; called by muse, mutect2, varscan2
- GBP2 | c.703G>A p.V235I | Missense Mutation (SNP) | VAF 71/227 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs199744522; called by muse, mutect2, varscan2
- GCC1 | c.2045A>G p.H682R | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV58462823; called by muse, mutect2, varscan2
- HSF2BP | c.322G>T p.E108* | Nonsense Mutation (SNP) | VAF 49/169 reads (29%) | catalogued as COSV52357303; called by muse, mutect2, varscan2
- INPP5B | c.1243A>C p.K415Q (on ENST00000373023; = p.K335Q on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 101/367 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV65961329; called by muse, mutect2, varscan2
- ITGAD | c.1720T>G p.S574A | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.035); catalogued as COSV66758462; called by muse, mutect2
- KRTAP22-1 | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 64/215 reads (30%) | PolyPhen probably damaging (0.94); catalogued as rs754504713, COSV58182470; called by muse, mutect2, varscan2
- MRPL57 | c.186C>G p.H62Q | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs371867311, COSV53435176; called by muse, mutect2, varscan2
- NCKAP5L | c.2237A>C p.D746A | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.575); catalogued as COSV100258789; called by muse, mutect2
- NOC2L | c.938C>A p.A313D | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV58988243; called by muse, mutect2, varscan2
- NOL6 | c.2768A>C p.N923T | Missense Mutation (SNP) | VAF 55/221 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.019); catalogued as COSV53042759; called by muse, mutect2, varscan2
- OPRD1 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs750038268, COSV52382335; called by muse, mutect2, varscan2
- OR6T1 | c.364C>A p.R122S | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58306274, COSV58307592; called by muse, mutect2, varscan2
- PFDN4 | c.311G>T p.R104I | Missense Mutation (SNP) | VAF 144/435 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as COSV65063316; called by muse, mutect2, varscan2
- PHTF1 | c.524G>C p.R175P | Missense Mutation (SNP) | VAF 125/475 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.231); catalogued as COSV63367862; called by muse, mutect2, varscan2
- PLCH2 | c.3506G>A p.R1169H | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.288); catalogued as rs773774181, COSV53944974, COSV99059154; called by mutect2, varscan2
- PRPS1 | c.488G>A p.R163K | Missense Mutation (SNP) | VAF 137/477 reads (29%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV65054441; called by muse, mutect2, varscan2
- RNF220 | c.280C>A p.H94N | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.838); catalogued as COSV62407185; called by muse, mutect2, varscan2
- RPS11 | c.250A>G p.R84G | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); catalogued as COSV54526622; called by muse, mutect2, varscan2
- SERAC1 | c.338T>C p.L113P | Missense Mutation (SNP) | VAF 154/540 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV65596934; called by muse, varscan2
- SLC27A5 | c.1830G>C p.E610D | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV54020175; called by muse, mutect2, varscan2
- SLC9A5 | c.2281G>T p.E761* | Nonsense Mutation (SNP) | VAF 30/115 reads (26%) | catalogued as COSV55362794; called by muse, mutect2, varscan2
- SLC9A5 | c.2282A>G p.E761G | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.091); catalogued as COSV55362813; called by muse, mutect2, varscan2
- SLCO1C1 | c.1712C>T p.P571L | Missense Mutation (SNP) | VAF 53/386 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1486158038, COSV56874304; called by muse, mutect2, varscan2
- STAT3 | c.877T>A p.Y293N | Missense Mutation (SNP) | VAF 119/399 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52888814; called by muse, mutect2, varscan2
- STXBP5L | c.3497C>T p.A1166V | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs760154570, COSV56518086; called by muse, mutect2, varscan2
- TIA1 | c.977G>C p.G326A (on ENST00000433529 / NM_001351511.1; = p.G315A on NM_022037.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 82/263 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV57007032; called by muse, mutect2, varscan2
- TRPM7 | c.4781T>C p.I1594T | Missense Mutation (SNP) | VAF 98/304 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV57917782; called by muse, mutect2, varscan2
- UBR4 | c.10169A>G p.Q3390R | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.838); catalogued as COSV64391944; called by muse, mutect2
- UGGT1 | c.963G>A p.W321* | Nonsense Mutation (SNP) | VAF 79/256 reads (31%) | catalogued as rs1558767089, COSV52137150; called by muse, mutect2, varscan2
- ZNF318 | c.3724A>T p.N1242Y | Missense Mutation (SNP) | VAF 137/484 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as COSV58933619; called by muse, mutect2, varscan2
- ZNF346 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 61/266 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.12); catalogued as rs139233067; called by muse, mutect2, varscan2
- ZNF555 | c.1366C>A p.Q456K | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.246); catalogued as COSV62073348; called by muse, mutect2, varscan2
- ZNF790 | c.457C>G p.Q153E | Missense Mutation (SNP) | VAF 88/314 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV63212619; called by muse, mutect2, varscan2
- ZSCAN29 | c.404A>T p.Q135L | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.932); catalogued as COSV53019735; called by muse, mutect2, varscan2
- ADCY6 | c.2546del p.Y849Ffs*49 | Frame Shift Del (DEL) | VAF 37/143 reads (26%) | called by mutect2, pindel, varscan2
- CTNND2 | c.3263_3264del p.T1088Rfs*15 | Frame Shift Del (DEL) | VAF 116/633 reads (18%) | called by mutect2, pindel, varscan2
- CXADR | c.486_487del p.C162* | Frame Shift Del (DEL) | VAF 96/438 reads (22%) | called by pindel, varscan2
- GABRE | c.700dup p.I234Nfs*3 | Frame Shift Ins (INS) | VAF 248/614 reads (40%) | called by mutect2, pindel, varscan2
- HSPG2 | c.444_447delinsCGGTG p.D149Gfs*63 | Frame Shift Ins (INS) | VAF 48/154 reads (31%) | called by pindel, varscan2*
- MTMR3 | c.2160_2168del p.D720_L723delinsE | In Frame Del (DEL) | VAF 17/72 reads (24%) | called by mutect2, pindel, varscan2
- PBRM1 | c.1713del p.I571Mfs*16 | Frame Shift Del (DEL) | VAF 109/313 reads (35%) | called by mutect2, pindel, varscan2
- SH3TC1 | c.714del p.R238Sfs*38 | Frame Shift Del (DEL) | VAF 19/72 reads (26%) | called by mutect2, pindel, varscan2
- ZNF625 | c.1003_1004del p.Q335Mfs*3 | Frame Shift Del (DEL) | VAF 41/184 reads (22%) | called by mutect2, pindel, varscan2
- ADAMTS2 | c.2541C>T p.N847= | Silent (SNP) | VAF 71/169 reads (42%) | catalogued as rs1436992389, COSV52364795, COSV52366033, COSV99283334; called by muse, mutect2, varscan2
- CELF4 | c.1422G>A p.V474= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs769982791, COSV58456314; called by muse, mutect2, varscan2
- CFAP65 | c.3000C>G p.A1000= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV58562345, COSV58566455; called by muse, mutect2
- CHD9 | c.6714T>C p.N2238= | Silent (SNP) | VAF 83/267 reads (31%) | catalogued as COSV54611811; called by muse, mutect2, varscan2
- CHRNA9 | c.930C>T p.I310= | Silent (SNP) | VAF 47/161 reads (29%) | catalogued as COSV59574834; called by muse, mutect2, varscan2
- CLDN6 | c.39G>A p.L13= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV58509773, COSV58510760; called by muse, mutect2, varscan2
- FOXO3 | c.1356A>G p.Q452= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV59628948; called by muse, varscan2
- IL6ST | c.840C>A p.T280= | Silent (SNP) | VAF 198/468 reads (42%) | catalogued as COSV61141633; called by muse, mutect2, varscan2
- NCOR1 | c.2001T>C p.F667= | Silent (SNP) | VAF 192/662 reads (29%) | catalogued as COSV51979502; called by muse, mutect2, varscan2
- OPRM1 | c.918C>A p.A306= | Silent (SNP) | VAF 96/313 reads (31%) | catalogued as COSV57679117; called by muse, mutect2, varscan2
- PIANP | c.684G>A p.L228= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs1460944921, COSV57707814, COSV57708082; called by mutect2, varscan2
- PLAGL2 | c.1449G>A p.L483= | Silent (SNP) | VAF 38/108 reads (35%) | catalogued as COSV55788726; called by muse, mutect2, varscan2
- RNF31 | c.360A>G p.R120= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as rs1418916315, COSV53760225; called by muse, mutect2, varscan2
- SLCO1A2 | c.96C>A p.S32= | Silent (SNP) | VAF 129/441 reads (29%) | catalogued as COSV56604578; called by muse, mutect2, varscan2
- SMG5 | c.618A>T p.S206= | Silent (SNP) | VAF 65/218 reads (30%) | catalogued as COSV62435928; called by muse, mutect2, varscan2
- TTN | c.8601G>A p.V2867= (on ENST00000591111; = p.V2821= on NM_003319.4) | Silent (SNP) | VAF 112/412 reads (27%) | catalogued as COSV60132273; called by muse, mutect2, varscan2
- ZNF106 | c.702T>C p.N234= | Silent (SNP) | VAF 47/190 reads (25%) | catalogued as COSV55517827; called by muse, mutect2, varscan2
- ZNF423 | c.2310G>A p.E770= (on ENST00000563137 / NM_001379286.1; = p.E762= on NM_015069.4) | Silent (SNP) | VAF 42/159 reads (26%) | catalogued as COSV52193338; called by muse, mutect2, varscan2
- UBTFL2 | n.1025dup | RNA (INS) | VAF 7/24 reads (29%) | called by mutect2, varscan2
